Somatic mutation profile of tumor specimen MP2PRT-PATHAJ-TBP1-A (aliquot MP2PRT-PATHAJ-TBP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATHAJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (632 days).
Specimen MP2PRT-PATHAJ-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c01bc204-901b-4f47-b747-3c55786cf385.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATHAJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATHAJ-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ad0070b-f91a-4f77-9938-e4e5c74a098e

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5, Frame Shift Ins 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COBL | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 162/388 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753823896; called by muse, mutect2, varscan2
- OPHN1 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs375650816, COSV62785888; called by muse, mutect2, varscan2
- ROS1 | c.2953G>C p.E985Q | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.702); catalogued as COSV100875982; called by muse, mutect2, varscan2
- TBX22 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 143/674 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as COSV64787255; called by muse, mutect2, varscan2
- TRPV4 | c.2554C>T p.R852C | Missense Mutation (SNP) | VAF 114/518 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.083); catalogued as rs372583866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBA2 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55828644; called by muse, mutect2, varscan2
- BCOR | c.1179T>A p.Y393* | Nonsense Mutation (SNP) | VAF 22/744 reads (3%) | called by muse, mutect2
- IGHV3-48 | c.352_353insGCCAGGGAG | In Frame Ins (INS) | VAF 5/34 reads (15%) | called by mutect2, pindel
- PALLD | c.3118G>C p.D1040H (on ENST00000505667 / NM_001166108.2; = p.D1023H on NM_016081.4) | Missense Mutation (SNP) | VAF 74/368 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TNF | c.481_482insCGTCG p.V161Afs*163 | Frame Shift Ins (INS) | VAF 143/776 reads (18%) | called by mutect2, pindel, varscan2
- ANO2 | c.2523C>T p.H841= (on ENST00000356134 / NM_001278597.3; = p.H845= on NM_001278596.3) | Silent (SNP) | VAF 18/337 reads (5%) | catalogued as rs755523500; called by muse, mutect2
- MPST | c.648C>T p.F216= (on ENST00000341116 / NM_001369904.2; = p.F236= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/370 reads (3%) | catalogued as COSV62018839; called by muse, mutect2
- PRDM10 | c.912C>T p.G304= | Silent (SNP) | VAF 24/447 reads (5%) | called by muse, mutect2
- SOHLH2 | c.234C>T p.A78= | Silent (SNP) | VAF 61/290 reads (21%) | catalogued as rs376326296; called by muse, mutect2, varscan2
- TWIST1 | c.447C>G p.L149= | Silent (SNP) | VAF 98/456 reads (21%) | called by muse, mutect2, varscan2
